Surgical pathology report (de-identified scan), TCGA case TCGA-CD-5804, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-5804-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report
(For Collection of Cancerous Tissue)

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	[REDACTED]	[REDACTED]	Temperature
Gender	Weight	[REDACTED]	[REDACTED]	Heart Rate
☒ Male ☐ Female	[REDACTED]	[REDACTED]	[REDACTED]	

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain ; constipation ; vomit .

Symptoms: Tired of eating ; weight loss .

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)		
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy ✓	A lesion was found at the pylorus	
MRI		
Biopsy	Adenocarcinoma	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T ₃ N ₁ M ₀ Stage: III	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach tumor	pylorus	5 x 3 x cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃ N ₁ M ₀ Stage: III			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: [REDACTED]

Date: [REDACTED]

Time: [REDACTED]

Preserved by: [REDACTED]

Date: [REDACTED]

Time: [REDACTED]

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
[REDACTED]		[REDACTED]				min	

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	3 x 5 x cm	pyloric	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3	N 1	M 0	Stage: III

Notes:

Stomach node 1 (positive)

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution						Structural Pattern					
	+	-		+	-		+	-		+	-
Diffuse						Streaming					
Mosaic						Storiform					
Necrosis						Fibrosis					
Lymphocytic Infiltration						Palisading					
Vascular Invasion						Cystic Degeneration					
Clusterized						Bleeding					
Alveolar Formation						Myxoid Change					
Indian File						Psammoma/Calcification					

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: Well ☒ Moderate ☒ Poor ☐

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				

Nuclear Grade: 0 I II III

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma of the stomach
(moderately differentiated) Grade: II

Comments:

Stomach node 1 (positive)

Pathologist

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	A		Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized		X	Bleeding		
Alveolar Formation		A	Myxoid Change		
Indian File		2	Psmmoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	A		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	A		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		
Otherwise Specified: D1 80% D2 70% D3 70% D4 70% been seen 2/10											

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade				

Histological Diagnosis: Adenocarcinoma, G2

Comments: U. Carcinoma metastasized to LN.

Source: NCI Genomic Data Commons file 543cc377-6b3e-4199-bd1f-a5958244dbea (TCGA-CD-5804.8381B806-AFD3-4443-AFDF-E445D3559717.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).